Somatic mutation profile of tumor specimen d38f40fb-dd78-43b2-8b7b-4b6977 (aliquot d38f40fb-dd78-43b2-8b7b-4b6977_D6) from CPTAC case 01OV023, project CPTAC-2 (Retroperitoneum and peritoneum — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Peritoneum, NOS; FIGO stage: Stage IIIC.
Specimen d38f40fb-dd78-43b2-8b7b-4b6977: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b093d386-d93a-4374-8a71-f2fe21e3949a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen cd900fda-2bc7-495e-8e11-3ef2ac (Blood Derived Normal), aliquot cd900fda-2bc7-495e-8e11-3ef2ac_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7d42f61-8c31-49ee-bd44-c23318129bf0

The open-access MAF lists 188 somatic variants for this specimen: 129 protein-altering or splice-affecting, 35 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 35, Intron 10, Splice Site 7, RNA 7, Frame Shift Del 4, Nonsense Mutation 3, In Frame Del 3, 3'UTR 3, Translation Start Site 2, 5'UTR 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3145G>C p.G1049R | Missense Mutation (SNP) | VAF 95/257 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as rs121913277, CM126700, COSV55874453, COSV55878564, COSV55919873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 264/517 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.3583C>T p.H1195Y | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as rs769925505; called by muse, mutect2, varscan2
- AC011005.1 | c.1061C>T p.T354M | Missense Mutation (SNP) | VAF 59/486 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.52); catalogued as rs776126665; called by muse, mutect2, varscan2
- ARL5B | c.108C>T p.F36= | Splice Region (SNP) | VAF 49/148 reads (33%) | catalogued as rs775435183; called by muse, mutect2, varscan2
- ASXL2 | c.1312A>G p.M438V | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs761937994; called by muse, mutect2, varscan2
- ATP6V0D1 | c.1024G>T p.A342S | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.114); catalogued as rs751799655; called by muse, mutect2, varscan2
- ATP8A1 | c.1586C>G p.S529W | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV52532920; called by muse, mutect2, varscan2
- ATP8A1 | c.1585T>A p.S529T | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.3); catalogued as rs752183723; called by muse, mutect2, varscan2
- CACNA1G | c.1750G>A p.V584M | Missense Mutation (SNP) | VAF 68/409 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs781383568; called by muse, mutect2, varscan2
- CAPN6 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1460207541, COSV60696090; called by muse, mutect2, varscan2
- CC2D1A | c.2083C>T p.Q695* | Nonsense Mutation (SNP) | VAF 126/252 reads (50%) | catalogued as COSV58784876; called by muse, mutect2, varscan2
- CILP2 | c.2431G>A p.A811T | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753346659, COSV52275554; called by muse, mutect2, varscan2
- CKM | c.9C>A p.F3L | Missense Mutation (SNP) | VAF 102/262 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.561); catalogued as rs368649875; called by muse, mutect2, varscan2
- COG3 | c.2231-1G>C p.X744_splice | Splice Site (SNP) | VAF 9/40 reads (23%) | catalogued as COSV63071941; called by muse, mutect2, varscan2
- KIFC3 | c.818G>A p.S273N | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs200822275; called by muse, mutect2, varscan2
- MAP4K4 | c.2129C>T p.S710F (on ENST00000347699 / NM_001242559.2; = p.S625F on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as rs1209664902; called by muse, mutect2, varscan2
- NCBP2L | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs868470604, COSV100966523; called by muse, mutect2, varscan2
- OR10V1 | c.534C>A p.F178L | Missense Mutation (SNP) | VAF 73/326 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55701436; called by muse, mutect2, varscan2
- OR1A2 | c.412C>G p.P138A | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as COSV67936536; called by muse, mutect2, varscan2
- OR8H3 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 85/427 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs751685926, COSV57909832, COSV57912321; called by muse, mutect2, varscan2
- PLA2R1 | c.1609G>C p.D537H | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV51778585, COSV51780843; called by muse, mutect2, varscan2
- PPARG | c.510G>C p.K170N (on ENST00000287820 / NM_015869.5; = p.K140N on NM_005037.7) | Missense Mutation (SNP) | VAF 71/359 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1214981971; called by muse, mutect2, varscan2
- PTPN12 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1461670446; called by muse, mutect2, varscan2
- SASH1 | c.3167G>C p.R1056T | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.225); catalogued as COSV66565835; called by muse, mutect2, varscan2
- SCAF8 | c.955C>G p.L319V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs779597183; called by muse, varscan2
- SGSM3 | c.2173-4G>A | Splice Region (SNP) | VAF 29/158 reads (18%) | catalogued as rs760619496; called by muse, mutect2, varscan2
- SLAMF1 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 66/221 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.049); catalogued as rs753033265, COSV52501994; called by muse, mutect2, varscan2
- SPEN | c.10961C>G p.S3654C | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV65271604; called by muse, mutect2, varscan2
- TNIK | c.1435C>G p.Q479E | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV52676635; called by muse, mutect2, varscan2
- TTC37 | c.1613G>C p.S538T | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.795); catalogued as rs1311294972, COSV62453492; called by muse, mutect2, varscan2
- TTN | c.25531+1G>T p.X8511_splice (on ENST00000591111; = p.X7584_splice on NM_133378.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 34/204 reads (17%) | catalogued as COSV60412633; called by mutect2, varscan2
- UGT2B4 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376958181; called by muse, mutect2, varscan2
- AC099489.1 | c.3515T>G p.L1172R | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- ADAMTS2 | c.1811C>G p.A604G | Missense Mutation (SNP) | VAF 78/407 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRL3 | c.3766T>A p.S1256T (on ENST00000506720 / NM_001322402.2; = p.S1188T on NM_015236.6) | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- ALDH1L2 | c.1318A>C p.K440Q | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- ANKRD45 | c.770A>T p.Q257L | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- ARFGEF2 | c.532A>T p.N178Y | Missense Mutation (SNP) | VAF 115/373 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AXDND1 | c.1447A>G p.I483V | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- B3GNT7 | c.883C>G p.P295A | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BPHL | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- C1orf21 | c.-25_12del | Translation Start Site (DEL) | VAF 20/91 reads (22%) | called by mutect2, pindel, varscan2
- CA2 | c.270G>C p.L90F | Missense Mutation (SNP) | VAF 54/429 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- CCDC102B | c.1336C>G p.H446D | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- CCDC87 | c.950A>G p.E317G | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CCSER2 | c.2405G>C p.R802T | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CSMD3 | c.1538A>G p.D513G (on ENST00000297405 / NM_001363185.1; = p.D409G on NM_052900.3) | Missense Mutation (SNP) | VAF 64/421 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DISP3 | c.3776A>C p.Y1259S | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DNAH6 | c.8660C>A p.A2887D | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK11 | c.500T>C p.I167T | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- DTX2 | c.1211T>G p.L404R | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.047); called by muse, varscan2
- EDNRA | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- ENAH | c.1388C>T p.S463L | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- ETNK1 | c.555A>T p.K185N | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FAM13B | c.246_269del p.E82_A89del | In Frame Del (DEL) | VAF 23/134 reads (17%) | called by mutect2, pindel, varscan2
- FCRL6 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 62/565 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- GMCL2 | c.1550A>T p.N517I | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.246); called by muse, mutect2
- GPR137B | c.89C>A p.P30Q | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); called by mutect2, varscan2
- HELB | c.1218A>T p.K406N | Missense Mutation (SNP) | VAF 59/234 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- IDH3B | c.521T>G p.L174R | Missense Mutation (SNP) | VAF 242/553 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- IGKV6-21 | c.283A>T p.N95Y | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2
- IREB2 | c.2864T>C p.L955S | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNK17 | c.661A>T p.T221S | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM3A | c.3715G>T p.D1239Y | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1522 | c.569G>T p.G190V (on ENST00000373480 / NM_001198972.2; = p.G249V on NM_020888.3) | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- KLHL26 | c.404_447del p.D135Gfs*88 | Frame Shift Del (DEL) | VAF 69/181 reads (38%) | called by mutect2, pindel, varscan2
- KMT2D | c.11664A>C p.K3888N | Missense Mutation (SNP) | VAF 52/255 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.075); called by muse, varscan2
- KYNU | c.434T>C p.M145T | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LACTB | c.560T>C p.I187T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LMBRD1 | c.1496T>A p.V499D (on ENST00000649011; = p.V477D on NM_018368.4) | Missense Mutation (SNP) | VAF 46/349 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- LMO3 | c.133T>A p.C45S | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2
- LRFN1 | c.2143C>A p.Q715K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- MALRD1 | c.3076_3079+12del p.X1026_splice | Splice Site (DEL) | VAF 11/71 reads (15%) | called by mutect2, pindel, varscan2
- MON2 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRTFA | c.902C>G p.A301G | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NBPF12 | c.2500G>T p.E834* | Nonsense Mutation (SNP) | VAF 70/535 reads (13%) | called by muse, mutect2, varscan2
- NKX2-6 | c.119A>T p.N40I | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.11); called by mutect2, varscan2
- NR4A2 | c.704T>C p.L235P | Missense Mutation (SNP) | VAF 56/576 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- OASL | c.127_134del p.F43Afs*127 | Frame Shift Del (DEL) | VAF 69/506 reads (14%) | called by mutect2, pindel, varscan2
- OBSCN | c.19252C>T p.H6418Y | Missense Mutation (SNP) | VAF 64/432 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- OR10H3 | c.64del p.Q22Sfs*13 | Frame Shift Del (DEL) | VAF 15/142 reads (11%) | called by mutect2, pindel, varscan2
- OR51E2 | c.652T>G p.F218V | Missense Mutation (SNP) | VAF 122/519 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- OR52N4 | c.146A>C p.Y49S | Missense Mutation (SNP) | VAF 56/281 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- PAAF1 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PAK5 | c.1292A>C p.Q431P | Missense Mutation (SNP) | VAF 96/221 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- PATL2 | c.570G>T p.M190I | Missense Mutation (SNP) | VAF 74/213 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- PCDH17 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 118/434 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PDE6A | c.1201G>C p.A401P | Missense Mutation (SNP) | VAF 66/302 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PINLYP | c.335T>C p.L112S | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- POLE | c.1854G>C p.E618D | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- POU4F2 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.429); called by muse, mutect2
- PPIG | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP3R1 | c.262A>T p.K88* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- PRDM2 | c.2517G>C p.K839N | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- PTCHD4 | c.428A>G p.D143G | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PTPRB | c.1778A>T p.N593I | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by mutect2, varscan2
- RGS22 | c.3709G>T p.G1237C | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- RIF1 | c.156A>C p.K52N | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RNF14 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- RNF157 | c.610G>T p.V204L | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by mutect2, varscan2
- RPL6 | c.262G>T p.V88F | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- SATB2 | c.365G>A p.R122K | Missense Mutation (SNP) | VAF 76/399 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SH2D2A | c.1034A>C p.N345T | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SHF | c.1085+1G>A p.X362_splice | Splice Site (SNP) | VAF 42/133 reads (32%) | called by muse, mutect2, varscan2
- SLC22A8 | c.1084T>A p.F362I | Missense Mutation (SNP) | VAF 92/465 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC35F5 | c.835C>G p.L279V | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC39A4 | c.86T>A p.L29Q | Missense Mutation (SNP) | VAF 79/676 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SPTBN1 | c.300+1G>T p.X100_splice | Splice Site (SNP) | VAF 17/131 reads (13%) | called by muse, mutect2, varscan2
- SREBF1 | c.1650del p.W550Cfs*148 | Frame Shift Del (DEL) | VAF 85/525 reads (16%) | called by mutect2, pindel, varscan2
- STK32B | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SYNE2 | c.13159-1G>C p.X4387_splice | Splice Site (SNP) | VAF 36/189 reads (19%) | called by muse, mutect2, varscan2
- TBC1D4 | c.1733G>T p.G578V | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); called by mutect2, varscan2
- TBP | c.497+2T>A p.X166_splice | Splice Site (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- TERT | c.1540G>C p.V514L | Missense Mutation (SNP) | VAF 53/347 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIGD7 | c.1529A>G p.E510G | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- TLK2 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM200A | c.862T>A p.F288I | Missense Mutation (SNP) | VAF 317/553 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM63B | c.1196G>T p.S399I | Missense Mutation (SNP) | VAF 110/247 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- TTLL6 | c.867_875delinsTTT p.R290_A292delinsL | In Frame Del (DEL) | VAF 55/104 reads (53%) | called by pindel, varscan2*
- TTN | c.7232T>A p.M2411K (on ENST00000591111; = p.M2365K on NM_003319.4) | Missense Mutation (SNP) | VAF 96/527 reads (18%) | PolyPhen benign (0.006); called by muse, mutect2, varscan2
- UPF3A | c.789C>G p.C263W | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- UTP20 | c.1509A>G p.I503M | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- WDR31 | c.238G>A p.G80R (on ENST00000374193 / NM_001006615.3; = p.G79R on NM_145241.5) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- WFDC10B | c.158A>C p.K53T | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.042); called by muse, mutect2
- ZMYM6 | c.650G>T p.S217I | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF106 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF518A | c.2890C>G p.Q964E | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ZNF638 | c.3518_3520del p.E1173del | In Frame Del (DEL) | VAF 36/186 reads (19%) | called by pindel, varscan2
- AHNAK2 | c.14352C>G p.L4784= | Silent (SNP) | VAF 37/179 reads (21%) | called by muse, mutect2, varscan2
- ALB | c.882G>A p.S294= | Silent (SNP) | VAF 70/395 reads (18%) | catalogued as rs143665140, COSV99891576; called by muse, mutect2, varscan2
- ASCL1 | c.273G>C p.S91= | Silent (SNP) | VAF 40/179 reads (22%) | catalogued as rs749824853; called by muse, mutect2, varscan2
- ATP8B4 | c.525C>G p.V175= | Silent (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- BCL2L12 | c.708C>T p.S236= | Silent (SNP) | VAF 21/107 reads (20%) | called by muse, mutect2, varscan2
- CAPN13 | c.75G>A p.R25= | Silent (SNP) | VAF 23/148 reads (16%) | catalogued as rs371887475, COSV54431137; called by muse, mutect2, varscan2
- CEBPE | c.840C>T p.C280= | Silent (SNP) | VAF 46/314 reads (15%) | called by muse, mutect2, varscan2
- CR2 | c.1449G>A p.Q483= | Silent (SNP) | VAF 154/872 reads (18%) | called by muse, mutect2, varscan2
- GALR2 | c.996C>G p.G332= | Silent (SNP) | VAF 78/441 reads (18%) | called by muse, mutect2, varscan2
- HECW1 | c.1680C>T p.Y560= | Silent (SNP) | VAF 46/313 reads (15%) | called by muse, mutect2, varscan2
- JARID2 | c.1779G>A p.P593= | Silent (SNP) | VAF 30/462 reads (6%) | catalogued as rs757218487, COSV59194058; called by muse, mutect2
- KCNK13 | c.147C>G p.A49= | Silent (SNP) | VAF 32/113 reads (28%) | called by muse, mutect2, varscan2
- LARP7 | c.39A>G p.E13= | Silent (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- LONRF2 | c.1950C>G p.A650= | Silent (SNP) | VAF 22/137 reads (16%) | called by muse, mutect2, varscan2
- LRIT1 | c.105T>A p.G35= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV63893722; called by muse, mutect2, varscan2
- MAPT | c.2016G>A p.K672= (on ENST00000262410 / NM_001377265.1; = p.K280= on NM_005910.5) | Silent (SNP) | VAF 174/440 reads (40%) | catalogued as rs182024939; called by muse, mutect2, varscan2
- MED12L | c.2268T>C p.N756= | Silent (SNP) | VAF 7/212 reads (3%) | called by muse, mutect2
- MOSPD3 | c.453G>A p.A151= | Silent (SNP) | VAF 55/226 reads (24%) | catalogued as rs201614846; called by muse, mutect2, varscan2
- NIPSNAP3B | c.399A>G p.P133= | Silent (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
- OSBPL6 | c.1053T>C p.D351= | Silent (SNP) | VAF 41/194 reads (21%) | called by muse, mutect2, varscan2
- OTOG | c.4596G>C p.V1532= | Silent (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- PARP16 | c.735T>C p.S245= | Silent (SNP) | VAF 20/111 reads (18%) | called by muse, mutect2, varscan2
- PKN3 | c.1326G>A p.L442= | Silent (SNP) | VAF 30/116 reads (26%) | called by muse, mutect2, varscan2
- PLXDC1 | c.915G>A p.L305= | Silent (SNP) | VAF 125/189 reads (66%) | catalogued as rs772527303; called by muse, mutect2, varscan2
- PSMD1 | c.2632T>C p.L878= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as rs1350829114; called by muse, mutect2, varscan2
- SLC6A13 | c.879T>C p.C293= | Silent (SNP) | VAF 59/243 reads (24%) | called by muse, mutect2, varscan2
- SLC9A2 | c.2091C>T p.D697= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as rs759669566, COSV52135011; called by muse, mutect2, varscan2
- SP9 | c.1152G>C p.R384= | Silent (SNP) | VAF 44/278 reads (16%) | called by muse, mutect2, varscan2
- SSH3 | c.1089G>C p.R363= | Silent (SNP) | VAF 23/137 reads (17%) | called by muse, mutect2, varscan2
- SSTR3 | c.1002T>G p.R334= | Silent (SNP) | VAF 42/209 reads (20%) | called by mutect2, varscan2
- ST6GALNAC4 | c.879G>C p.V293= | Silent (SNP) | VAF 12/83 reads (14%) | called by mutect2, varscan2
- TFPI2 | c.495A>C p.G165= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- TMC2 | c.1170C>A p.I390= | Silent (SNP) | VAF 46/122 reads (38%) | called by muse, mutect2, varscan2
- TNFRSF4 | c.630C>A p.P210= | Silent (SNP) | VAF 33/180 reads (18%) | catalogued as COSV55422338; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2559C>T p.G853= | Silent (SNP) | VAF 18/296 reads (6%) | called by muse, mutect2
- ABCA4 | c.2919-991C>T | Intron (SNP) | VAF 18/164 reads (11%) | called by muse, mutect2, varscan2
- ATP8A1 | c.-24G>A | 5'UTR (SNP) | VAF 21/102 reads (21%) | called by muse, varscan2
- BRD4 | c.2158+573G>C | Intron (SNP) | VAF 37/135 reads (27%) | called by muse, mutect2, varscan2
- C5orf60 | n.117G>T | RNA (SNP) | VAF 92/676 reads (14%) | called by muse, mutect2, varscan2
- CEP41 | c.*4080G>C | 3'UTR (SNP) | VAF 89/619 reads (14%) | called by mutect2, varscan2
- CFAP94 | c.-37C>G | 5'UTR (SNP) | VAF 22/179 reads (12%) | catalogued as rs1165687589; called by muse, mutect2, varscan2
- COL16A1 | c.4101+56_4101+91del | Intron (DEL) | VAF 14/82 reads (17%) | called by mutect2, pindel, varscan2
- CTU2 | c.144-9G>C | Intron (SNP) | VAF 34/101 reads (34%) | called by muse, mutect2, varscan2
- DST | c.414+7206A>G | Intron (SNP) | VAF 30/258 reads (12%) | called by muse, mutect2, varscan2
- EP400P1 | n.868G>C | RNA (SNP) | VAF 52/194 reads (27%) | called by mutect2, varscan2
- GUSB | c.1245-11C>G | Intron (SNP) | VAF 114/529 reads (22%) | catalogued as rs753108318; called by muse, mutect2, varscan2
- HSD17B7P2 | n.318C>T | RNA (SNP) | VAF 9/54 reads (17%) | catalogued as rs1159299825; called by muse, mutect2, varscan2
- OR7A2P | n.758C>A | RNA (SNP) | VAF 53/92 reads (58%) | called by muse, mutect2, varscan2
- PARGP1 | n.1382T>C | RNA (SNP) | VAF 32/112 reads (29%) | called by muse, mutect2, varscan2
- PLEKHH3 | c.2013+48C>T | Intron (SNP) | VAF 66/124 reads (53%) | called by muse, mutect2, varscan2
- PLEKHM1 | c.*1442G>A | 3'UTR (SNP) | VAF 118/244 reads (48%) | catalogued as rs918398635; called by muse, mutect2, varscan2
- PTPRF | c.679+261G>T | Intron (SNP) | VAF 93/588 reads (16%) | called by muse, mutect2, varscan2
- RN7SL211P | chr2:64905057 C>A | 3'Flank (SNP) | VAF 32/144 reads (22%) | called by mutect2, varscan2
- SCN8A | c.3820-389T>C | Intron (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- SLC6A10P | n.3731G>A | RNA (SNP) | VAF 59/410 reads (14%) | catalogued as rs746134886; called by muse, mutect2, varscan2
- SSR2 | c.155+762A>G | Intron (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2, varscan2
- SUPT5H | chr19:39441296 G>T | 5'Flank (SNP) | VAF 62/100 reads (62%) | called by muse, mutect2, varscan2
- SYNPO2L | c.*1736G>A | 3'UTR (SNP) | VAF 14/44 reads (32%) | catalogued as rs938516495; called by muse, mutect2, varscan2
- TRIM51EP | n.1263A>C | RNA (SNP) | VAF 28/113 reads (25%) | called by mutect2, varscan2
